Somatic mutation profile of tumor specimen TARGET-10-PAPART-09A (aliquot TARGET-10-PAPART-09A-01D) from TARGET case TARGET-10-PAPART, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.2 years (805 days).
Specimen TARGET-10-PAPART-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 70e9f1cb-1512-4f6f-ba50-b9d8e9e2ba67.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPART-14A (Bone Marrow Normal), aliquot TARGET-10-PAPART-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1718672a-0ba1-4159-8e4e-354e1f9f8658

The open-access MAF lists 35 somatic variants for this specimen: 21 protein-altering or splice-affecting, 7 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 7, Intron 4, 3'UTR 2, 5'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABHD17B | c.596G>A p.R199Q | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1191236747; called by muse, mutect2, varscan2
- AMBN | c.1142C>A p.A381E | Missense Mutation (SNP) | VAF 29/221 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.87); catalogued as rs958644618; called by muse, mutect2, varscan2
- CECR2 | c.145C>A p.H49N | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.852); catalogued as rs778366296; called by muse, mutect2
- CGNL1 | c.436C>G p.Q146E | Missense Mutation (SNP) | VAF 9/174 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV99849407; called by muse, mutect2
- DECR2 | c.662G>A p.G221D | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.089); catalogued as COSV54795895; called by muse, mutect2, varscan2
- MAST4 | c.3359C>G p.S1120C (on ENST00000403625 / NM_001164664.2; = p.S931C on NM_015183.3) | Missense Mutation (SNP) | VAF 4/90 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs979322298; called by muse, mutect2
- NLGN3 | c.2243G>T p.R748L (on ENST00000358741 / NM_181303.2; = p.R728L on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.666); catalogued as rs748757954, COSV62442318; called by muse, mutect2, varscan2
- PRKCA | c.662C>T p.P221L | Missense Mutation (SNP) | VAF 28/167 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs759130548; called by muse, mutect2, varscan2
- SEPTIN4 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 13/136 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.221); catalogued as rs752008813; called by muse, mutect2
- TECPR2 | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.081); catalogued as COSV100850266; called by muse, mutect2
- ZNF875 | c.923G>A p.R308Q | Missense Mutation (SNP) | VAF 16/216 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.283); catalogued as rs368976173; called by muse, mutect2
- CFHR3 | c.701G>C p.R234T | Missense Mutation (SNP) | VAF 20/187 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- CHAD | c.359A>G p.D120G | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); called by muse, mutect2
- DYNC1I1 | c.1759C>T p.Q587* | Nonsense Mutation (SNP) | VAF 5/72 reads (7%) | called by muse, mutect2
- EHBP1L1 | c.1423C>A p.P475T | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- FMNL2 | c.716A>C p.N239T | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- GRIK2 | c.1558A>C p.T520P | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- KCNT2 | c.789T>G p.I263M | Missense Mutation (SNP) | VAF 9/181 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MAGEL2 | c.2145G>T p.M715I | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- TG | c.2155G>A p.A719T | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.6); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- UBA2 | c.569A>G p.K190R | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- BVES | c.327G>A p.S109= | Silent (SNP) | VAF 11/131 reads (8%) | catalogued as rs139347341; called by muse, mutect2
- COL6A6 | c.4407C>T p.N1469= | Silent (SNP) | VAF 40/243 reads (16%) | catalogued as rs774517921, COSV62016806; called by muse, mutect2, varscan2
- PCNT | c.810G>A p.Q270= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV64025854; called by muse, mutect2, varscan2
- SALL3 | c.1506G>A p.S502= | Silent (SNP) | VAF 19/106 reads (18%) | catalogued as rs774287520, COSV101609926; called by muse, mutect2, varscan2
- TENM2 | c.4395C>T p.L1465= (on ENST00000518659 / NM_001122679.2; = p.L1226= on NM_001080428.3) | Silent (SNP) | VAF 31/166 reads (19%) | called by muse, mutect2, varscan2
- UNC13B | c.3703C>A p.R1235= | Silent (SNP) | VAF 10/190 reads (5%) | catalogued as COSV65936656; called by muse, mutect2
- ZNF557 | c.1059C>T p.S353= (on ENST00000414706 / NM_001044388.2; = p.S360= on NM_024341.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as rs1210882464; called by muse, mutect2, varscan2
- ADGRF2 | c.277-4375G>T | Intron (SNP) | VAF 14/82 reads (17%) | catalogued as rs868787650, COSV57290722; called by muse, mutect2, varscan2
- KIRREL3 | c.56-119069C>G | Intron (SNP) | VAF 4/26 reads (15%) | called by muse, mutect2
- NDUFC1 | c.-39C>T | 5'UTR (SNP) | VAF 14/129 reads (11%) | catalogued as rs978617686; called by muse, mutect2, varscan2
- NELL2 | c.*61dup | 3'UTR (INS) | VAF 5/34 reads (15%) | called by mutect2, pindel, varscan2
- PGLYRP2 | c.1641+112C>T | Intron (SNP) | VAF 4/81 reads (5%) | called by muse, mutect2
- SLC2A1 | c.*323G>C | 3'UTR (SNP) | VAF 9/55 reads (16%) | called by muse, mutect2, varscan2
- SPOCK2 | c.189+1422C>T | Intron (SNP) | VAF 6/24 reads (25%) | called by muse, mutect2, varscan2
